Somatic mutation profile of tumor specimen TCGA-CD-8530-01A (aliquot TCGA-CD-8530-01A-11D-2340-08) from TCGA case TCGA-CD-8530, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 52.0 years (18,992 days).
Specimen TCGA-CD-8530-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7dd1d3d-aaf0-4a10-ae2e-507e055ec892.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8530-10A (Blood Derived Normal), aliquot TCGA-CD-8530-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/720282ff-b3af-4f95-b428-1639e5f0f6e0

The open-access MAF lists 84 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 20, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 2, RNA 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.332T>A p.L111Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADD3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV53323400; called by muse, mutect2, varscan2
- AKAP6 | c.5070A>C p.E1690D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55229701; called by muse, mutect2, varscan2
- ARMCX1 | c.1146T>G p.D382E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as COSV65705472; called by muse, mutect2, varscan2
- CACNA1C | c.2263A>G p.N755D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59717105; called by muse, mutect2, varscan2
- CELSR3 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1281504424, COSV51137787; called by muse, mutect2, varscan2
- CHRNB3 | c.941C>G p.T314S | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51497272; called by muse, mutect2, varscan2
- COL12A1 | c.9011-1G>A p.X3004_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV59405795; called by muse, mutect2, varscan2
- COMP | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771292272, COSV55876382; called by muse, mutect2, varscan2
- CST1 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV59054667; called by muse, mutect2
- CST8 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs149763863, COSV55672000; called by muse, mutect2, varscan2
- DCDC1 | c.2422T>G p.L808V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.038); catalogued as COSV60851284; called by muse, mutect2, varscan2
- DDX41 | c.642C>T p.T214= | Splice Region (SNP) | VAF 16/88 reads (18%) | catalogued as COSV57254224; called by muse, mutect2, varscan2
- DNER | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV100520056; called by muse, mutect2
- DOCK3 | c.467A>C p.H156P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV56545700; called by muse, mutect2
- EBF1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776402214, COSV58168864; called by muse, mutect2, varscan2
- FAM135B | c.1303A>C p.S435R | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV52713366; called by muse, mutect2
- GJA10 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65356035; called by muse, mutect2, varscan2
- GLG1 | c.3467G>T p.C1156F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV52673488; called by muse, mutect2, varscan2
- IGF2R | c.3309G>C p.R1103S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV63632183; called by muse, mutect2, varscan2
- LRP1B | c.3981A>T p.E1327D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV67202080, COSV67279079; called by muse, mutect2
- MUC21 | c.1085A>T p.N362I | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV66221982; called by muse, mutect2
- NALCN | c.2995C>G p.L999V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51960269; called by muse, mutect2
- NPEPL1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs751090870, COSV61940430; called by mutect2, varscan2
- OR4A15 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV59034939; called by muse, mutect2, varscan2
- OR52E6 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61433142; called by muse, mutect2
- OR5D13 | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs112091941, COSV62335074; called by muse, mutect2, varscan2
- OR5I1 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56888830; called by muse, mutect2, varscan2
- PCDHGB1 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs995541250, COSV53974235; called by muse, mutect2, varscan2
- PCDHGB2 | c.1490A>C p.K497T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV53983649, COSV54016794; called by muse, mutect2, varscan2
- PLA2G4C | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748557112, COSV62784538; called by muse, mutect2, varscan2
- PLCL1 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70868000; called by muse, mutect2, varscan2
- PLCL2 | c.712G>T p.V238F (on ENST00000615277 / NM_001144382.2; = p.V112F on NM_015184.5) | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as COSV67624682; called by muse, mutect2, varscan2
- PNMA3 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs782242475, COSV64721743; called by muse, mutect2, varscan2
- PSG11 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV100105290, COSV60457450; called by muse, mutect2, varscan2
- PTPRB | c.2764G>T p.D922Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54251353; called by muse, mutect2, varscan2
- RYR2 | c.264A>T p.K88N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV63697708, COSV63709227; called by muse, mutect2, varscan2
- SACM1L | c.132C>T p.V44= | Splice Region (SNP) | VAF 17/49 reads (35%) | catalogued as COSV66614902; called by muse, mutect2
- SGK1 | c.1027A>G p.K343E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52814293; called by muse, mutect2, varscan2
- SIX1 | c.844T>G p.L282V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55960878; called by muse, mutect2
- SPTA1 | c.5950A>G p.R1984G | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs886041244, COSV63758195; called by muse, mutect2
- SRRT | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1193069484, COSV53820985; called by muse, mutect2
- SVEP1 | c.2552A>C p.K851T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.321); catalogued as COSV57045610; called by muse, mutect2, varscan2
- SVOPL | c.835C>T p.R279W (on ENST00000419765; = p.R127W on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs149009334; called by mutect2, varscan2
- SYK | c.1342A>T p.M448L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV65329833; called by muse, mutect2, varscan2
- TDRD3 | c.1604C>G p.S535C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs886142475, COSV52162489; called by muse, mutect2, varscan2
- TENM3 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs748680947, COSV69317215; called by muse, mutect2, varscan2
- TTN | c.77238T>G p.C25746W (on ENST00000591111; = p.C18322W on NM_003319.4) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | PolyPhen probably damaging (0.938); catalogued as COSV60294300; called by muse, mutect2, varscan2
- TUT4 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757429088, COSV57118597, COSV99932586; called by muse, mutect2, varscan2
- UNC79 | c.2306G>A p.R769H (on ENST00000393151 / NM_001346218.2; = p.R592H on NM_020818.5) | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs188822336, COSV56382958; called by muse, mutect2, varscan2
- UNC79 | c.3754C>T p.R1252* (on ENST00000393151 / NM_001346218.2; = p.R1075* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs1253600542, COSV56375172; called by muse, mutect2, varscan2
- UPRT | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV64912625; called by muse, mutect2, varscan2
- VPS13D | c.9617C>T p.T3206M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs756820834, COSV50673916; called by muse, mutect2, varscan2
- ZBTB49 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61925973; called by muse, mutect2, varscan2
- ZFC3H1 | c.3145G>T p.E1049* | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | catalogued as COSV66431134; called by muse, mutect2
- ZFP14 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as COSV54204462; called by muse, mutect2, varscan2
- CDC23 | c.689_692del p.K230Sfs*13 | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel
- CKAP4 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- FHOD3 | c.3140T>C p.L1047P (on ENST00000359247 / NM_001281739.3; = p.L1064P on NM_025135.5) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIR2DL4 | c.1142C>G p.S381C (on ENST00000396284; = p.S307C on NM_001080770.2) | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NIBAN1 | c.406_419del p.S136Pfs*8 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- ARMCX3 | c.321A>G p.K107= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV57871487; called by muse, mutect2, varscan2
- CNTNAP5 | c.2598T>G p.P866= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV70508249; called by muse, mutect2, varscan2
- COL23A1 | c.303C>T p.D101= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs373172383; called by muse, mutect2, varscan2
- DHX57 | c.2067G>A p.S689= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs147299842; called by muse, mutect2, varscan2
- DPEP3 | c.735C>T p.S245= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs757018265, COSV52052661; called by muse, mutect2, varscan2
- FIGNL1 | c.654A>G p.T218= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs1230290683, COSV63554001; called by muse, mutect2, varscan2
- H2AB1 | c.216C>T p.G72= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57706372; called by mutect2, varscan2
- HBG2 | c.210T>G p.T70= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs768094911, COSV57963509, COSV57963783; called by muse, mutect2
- KCNB2 | c.117C>A p.I39= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV73052538; called by muse, mutect2
- MLXIP | c.1323C>T p.P441= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs776624139, COSV59837614; called by muse, mutect2, varscan2
- NEXMIF | c.3069T>G p.T1023= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV50057652, COSV50086591; called by muse, mutect2, varscan2
- OR2D3 | c.333T>C p.Y111= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV58573810; called by muse, varscan2
- PCLO | c.11817A>G p.Q3939= | Silent (SNP) | VAF 85/424 reads (20%) | catalogued as rs767020612, COSV100428853, COSV61660580, COSV61676960; called by muse, mutect2, varscan2
- PRL | c.75C>T p.S25= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1181973890, COSV60593474; called by muse, mutect2, varscan2
- PSG8 | c.258T>C p.G86= | Silent (SNP) | VAF 96/333 reads (29%) | catalogued as COSV60615014; called by muse, mutect2, varscan2
- SMC3 | c.1710G>A p.T570= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs1391232237, COSV62421803; called by muse, mutect2, varscan2
- TECRL | c.603C>A p.T201= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs768226181, COSV67087680, COSV67090019; called by muse, mutect2, varscan2
- TYW5 | c.18C>G p.L6= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV54460971, COSV54461496; called by muse, mutect2, varscan2
- UMODL1 | c.3219G>A p.L1073= (on ENST00000408910 / NM_001004416.2; = p.L1201= on NM_173568.3) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1261526591, COSV68569604; called by muse, varscan2
- ZNF776 | c.900T>G p.S300= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV57816449; called by muse, mutect2, varscan2
- ETNK1 | c.946-2189A>G | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- RNF217-AS1 | n.1089C>T | RNA (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-38 | n.19T>G | RNA (SNP) | VAF 68/262 reads (26%) | called by muse, mutect2, varscan2
